Somatic mutation profile of cancer-model specimen HCM-WCMC-0952-C34-85A (3D Organoid; aliquot HCM-WCMC-0952-C34-85A-01D-A88H-36), derived from the primary tumor of HCMI case HCM-WCMC-0952-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Large cell neuroendocrine carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 74.0 years (27,036 days).
Specimen HCM-WCMC-0952-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 428072e7-0ce3-4e23-8087-88553a48331d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0952-C34-10A (Blood Derived Normal), aliquot HCM-WCMC-0952-C34-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16543b19-f8cc-46c0-bd5b-b3bf1b1d90b7

The open-access MAF lists 1,028 somatic variants for this specimen: 764 protein-altering or splice-affecting, 224 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 665, Silent 224, Nonsense Mutation 44, Intron 24, Frame Shift Del 18, Splice Site 13, Frame Shift Ins 9, Splice Region 7, 5'UTR 5, In Frame Del 5, 5'Flank 4, 3'Flank 3.

Variants (750 of 1,028; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR2 | c.1250G>T p.R417L | Missense Mutation (SNP) | VAF 243/424 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs751428303, COSV63688268, COSV63692084; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.782+1G>T p.X261_splice | Splice Site (SNP) | VAF 258/258 reads (100%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ACHE | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 136/554 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53815131; called by muse, mutect2, varscan2
- ACOX2 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 177/270 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1469171650; called by muse, mutect2, varscan2
- ACSM4 | c.916del p.L306* | Frame Shift Del (DEL) | VAF 82/368 reads (22%) | catalogued as COSV68069152; called by mutect2, pindel, varscan2
- ADAM19 | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 98/476 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV99067877; called by muse, mutect2, varscan2
- ADGRB3 | c.2481G>T p.T827= | Splice Region (SNP) | VAF 111/229 reads (48%) | catalogued as COSV99483594; called by muse, mutect2, varscan2
- AEBP1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 110/353 reads (31%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs750288301, COSV99788747; called by muse, mutect2, varscan2
- ALK | c.4019A>T p.E1340V | Missense Mutation (SNP) | VAF 104/393 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66563832; called by muse, mutect2, varscan2
- ANK1 | c.3416G>T p.R1139L | Missense Mutation (SNP) | VAF 361/527 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV55891781; called by muse, mutect2, varscan2
- ANO2 | c.2026C>A p.Q676K (on ENST00000356134 / NM_001278597.3; = p.Q680K on NM_001278596.3) | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1242974431; called by muse, mutect2, varscan2
- APBA3 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 150/450 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV99042371; called by muse, mutect2, varscan2
- ARID2 | c.3868G>T p.V1290L | Missense Mutation (SNP) | VAF 291/410 reads (71%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs777982636; called by muse, mutect2, varscan2
- ASB5 | c.118C>A p.H40N | Missense Mutation (SNP) | VAF 158/158 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV56668728; called by mutect2, varscan2
- ATP10A | c.2426G>T p.R809L | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776829827, COSV63516508, COSV63516647, COSV63518546; called by muse, mutect2, varscan2
- ATP11C | c.3396G>C p.L1132F | Missense Mutation (SNP) | VAF 73/73 reads (100%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV59569153; called by muse, mutect2, varscan2
- ATP2A3 | c.3006G>T p.R1002S | Missense Mutation (SNP) | VAF 297/298 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV59232323; called by muse, mutect2, varscan2
- ATP4A | c.2651T>C p.M884T | Missense Mutation (SNP) | VAF 414/565 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs769514644; called by muse, mutect2, varscan2
- BICDL2 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 129/533 reads (24%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.707); catalogued as COSV54156447; called by muse, mutect2, varscan2
- BNC1 | c.2618C>T p.S873F | Missense Mutation (SNP) | VAF 117/369 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs376033304; called by muse, mutect2, varscan2
- BSCL2 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 393/393 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV99628019; called by muse, mutect2, varscan2
- BTNL8 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 110/489 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.461); catalogued as COSV51460359; called by muse, mutect2, varscan2
- C12orf56 | c.1543A>G p.I515V (on ENST00000543942 / NM_001170633.2; = p.I355V on NM_001099676.3) | Missense Mutation (SNP) | VAF 185/282 reads (66%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs576278397; called by muse, mutect2, varscan2
- CACNA1E | c.2203G>T p.V735F | Missense Mutation (SNP) | VAF 59/294 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs528168265, COSV62395483; called by muse, mutect2, varscan2
- CCDC168 | c.18475C>A p.P6159T | Missense Mutation (SNP) | VAF 276/276 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV59425103; called by muse, mutect2, varscan2
- CCDC39 | c.2800G>A p.V934I | Missense Mutation (SNP) | VAF 75/449 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs886058197; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD48 | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 230/323 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs756875746; called by muse, mutect2, varscan2
- CDH20 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 140/492 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs868864755; called by muse, mutect2, varscan2
- CDH24 | c.1368G>A p.W456* | Nonsense Mutation (SNP) | VAF 114/309 reads (37%) | catalogued as rs1301312949; called by muse, mutect2, varscan2
- CDIP1 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 66/363 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs374465951; called by muse, mutect2, varscan2
- CDK14 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 277/373 reads (74%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs768515404; called by muse, mutect2, varscan2
- CENPF | c.8657C>T p.A2886V | Missense Mutation (SNP) | VAF 98/641 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV65275833; called by muse, mutect2, varscan2
- CEP128 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV53679068, COSV53679196; called by muse, mutect2, varscan2
- CFAP61 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 134/362 reads (37%) | catalogued as rs200778448; called by muse, mutect2, varscan2
- CGB5 | c.276C>A p.C92* | Nonsense Mutation (SNP) | VAF 38/142 reads (27%) | catalogued as rs1427884788; called by mutect2, varscan2
- CLASP1 | c.3713G>T p.R1238L | Missense Mutation (SNP) | VAF 136/264 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV55312830, COSV99752631; called by muse, mutect2, varscan2
- CLK4 | c.983C>G p.T328R | Missense Mutation (SNP) | VAF 53/297 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60318414; called by muse, mutect2, varscan2
- CLN8 | c.248G>T p.W83L | Missense Mutation (SNP) | VAF 442/445 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as rs780923228; called by muse, varscan2
- CNTNAP5 | c.2954C>T p.T985I | Missense Mutation (SNP) | VAF 78/181 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV70489147; called by muse, mutect2, varscan2
- COL3A1 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 165/281 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV58597871; called by muse, mutect2, varscan2
- COL4A2 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 301/302 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476249623, COSV64630856; called by muse, mutect2, varscan2
- COL6A2 | c.2380G>C p.A794P | Missense Mutation (SNP) | VAF 99/213 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV56004621; called by muse, mutect2, varscan2
- CR1 | c.2435T>C p.M812T | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1250324619; called by muse, mutect2, varscan2
- CSMD1 | c.9575C>G p.S3192C (on ENST00000520002; = p.S3191C on NM_033225.6) | Missense Mutation (SNP) | VAF 332/332 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59304948; called by muse, mutect2, varscan2
- CST2 | c.116T>A p.L39H | Missense Mutation (SNP) | VAF 177/332 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV59030211; called by muse, mutect2, varscan2
- CTDSPL | c.598C>G p.H200D (on ENST00000273179 / NM_001008392.2; = p.H189D on NM_005808.3) | Missense Mutation (SNP) | VAF 463/463 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV56205880; called by muse, mutect2, varscan2
- CTNNA3 | c.1982A>C p.K661T | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as COSV65520898; called by muse, mutect2, varscan2
- CYP2D6 | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 141/560 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs1166022405; called by muse, mutect2, varscan2
- DAOA | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 273/273 reads (100%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs757009026, COSV100298829, COSV61601843; called by muse, mutect2, varscan2
- DDI1 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 126/549 reads (23%) | catalogued as COSV56369663; called by muse, mutect2, varscan2
- DGKQ | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 140/889 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.415); catalogued as COSV56615807; called by muse, mutect2, varscan2
- DLEU7 | c.89G>T p.W30L | Missense Mutation (SNP) | VAF 122/368 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.058); catalogued as rs761070115; called by muse, varscan2
- DLGAP1 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 192/448 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV59839385; called by muse, mutect2, varscan2
- DNAAF1 | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 114/495 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs780536622; called by muse, mutect2, varscan2
- DNAH14 | c.5771G>T p.R1924L (on ENST00000445597; = p.R2464L on NM_001367479.1) | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs932845004; called by muse, mutect2, varscan2
- DNASE1L2 | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 138/611 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1341584024; called by mutect2, varscan2
- DOCK10 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV51421253; called by muse, mutect2, varscan2
- DPP10 | c.1243G>T p.V415L | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV59684506; called by muse, mutect2, varscan2
- DSC3 | c.936C>A p.D312E | Missense Mutation (SNP) | VAF 109/237 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs147196455; called by muse, mutect2, varscan2
- DVL3 | c.1028G>C p.G343A | Missense Mutation (SNP) | VAF 399/754 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as COSV100493609; called by muse, mutect2, varscan2
- EPHB6 | c.2164G>T p.A722S | Missense Mutation (SNP) | VAF 181/673 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.223); catalogued as rs370383805; called by muse, mutect2, varscan2
- ERCC3 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 152/313 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs753633161; called by muse, mutect2, varscan2
- EYA2 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 170/432 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs774269626; called by muse, mutect2, varscan2
- FAM47C | c.1085G>T p.R362L | Missense Mutation (SNP) | VAF 251/252 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.397); catalogued as rs149671724, COSV63725620; called by mutect2, varscan2
- FLG | c.2663G>A p.G888E | Missense Mutation (SNP) | VAF 146/647 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.428); catalogued as COSV64245104; called by muse, mutect2, varscan2
- FMN2 | c.3487C>T p.P1163S | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.961); catalogued as COSV100147732; called by muse, varscan2
- FN1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV100115977; called by muse, mutect2, varscan2
- FSIP2 | c.12223A>G p.I4075V | Missense Mutation (SNP) | VAF 83/311 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1260661207; called by muse, mutect2, varscan2
- FYCO1 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 251/411 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs769815234; called by muse, mutect2, varscan2
- GABRA2 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 100/406 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.721); catalogued as COSV100734542; called by muse, varscan2
- GDPD4 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 171/398 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.279); catalogued as COSV60019412; called by muse, mutect2, varscan2
- GIPC3 | c.652G>T p.G218W | Missense Mutation (SNP) | VAF 424/426 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59260993; called by muse, mutect2, varscan2
- GLP1R | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 179/433 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs148543734; called by muse, mutect2, varscan2
- GLP2R | c.1362C>G p.F454L | Missense Mutation (SNP) | VAF 227/228 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV52323474; called by muse, mutect2, varscan2
- GPR20 | c.584G>A p.C195Y | Missense Mutation (SNP) | VAF 468/1432 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs967035833; called by muse, mutect2, varscan2
- GRM8 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 187/406 reads (46%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.764); catalogued as rs1021001584, COSV58815708; called by muse, mutect2, varscan2
- GTF2H5 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 119/520 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs777480675; called by muse, mutect2, varscan2
- GYS1 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 204/860 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as rs370035815; called by muse, mutect2, varscan2
- HS3ST6 | c.493C>A p.R165S | Missense Mutation (SNP) | VAF 624/822 reads (76%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as COSV99562619, COSV99562884; called by muse, mutect2, varscan2
- HSD17B14 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 116/519 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV54363080; called by muse, mutect2, varscan2
- HTT | c.7441G>T p.V2481L | Missense Mutation (SNP) | VAF 470/591 reads (80%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV61866672; called by muse, mutect2, varscan2
- HUS1B | c.419G>C p.R140T | Missense Mutation (SNP) | VAF 69/770 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.665); catalogued as COSV100034247; called by muse, mutect2
- IGHV3-48 | c.197G>T p.W66L | Missense Mutation (SNP) | VAF 80/367 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.375); catalogued as rs1288243938; called by muse, mutect2, varscan2
- IGKV6D-21 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 140/340 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs776486396; called by muse, mutect2, varscan2
- IGLL5 | c.408T>A p.C136* | Nonsense Mutation (SNP) | VAF 155/317 reads (49%) | catalogued as rs565895977; called by muse, mutect2, varscan2
- INCENP | c.1564C>G p.R522G | Missense Mutation (SNP) | VAF 263/413 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99611645; called by muse, mutect2, varscan2
- ITGA4 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 121/345 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs539227893; called by muse, mutect2, varscan2
- ITPRID2 | c.2536C>T p.L846F | Missense Mutation (SNP) | VAF 140/439 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546606916; called by muse, mutect2, varscan2
- KCNA1 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 410/544 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV66836780; called by muse, varscan2
- KCNK2 | c.1069C>T p.R357W (on ENST00000444842 / NM_001017425.3; = p.R342W on NM_014217.4) | Missense Mutation (SNP) | VAF 352/579 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157701926, COSV67206955; called by muse, mutect2, varscan2
- KCNQ5 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 155/343 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100571331; called by muse, mutect2, varscan2
- KIAA0586 | c.4100C>A p.S1367Y (on ENST00000619416 / NM_001244190.2; = p.S1306Y on NM_014749.5) | Missense Mutation (SNP) | VAF 125/228 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as rs758384631; called by muse, mutect2, varscan2
- KMT2D | c.6563G>A p.R2188H | Missense Mutation (SNP) | VAF 228/878 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); catalogued as rs541122919, COSV56488488, COSV99987683; called by muse, mutect2, varscan2
- KPTN | c.994G>T p.G332* | Nonsense Mutation (SNP) | VAF 130/530 reads (25%) | catalogued as COSV52637876; called by muse, mutect2
- KRTAP25-1 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 292/292 reads (100%) | SIFT tolerated (0.86); PolyPhen benign (0.048); catalogued as rs942081236; called by muse, mutect2, varscan2
- LAMB1 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 243/352 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs774790976; called by muse, mutect2, varscan2
- LARGE1 | c.2037G>T p.W679C | Missense Mutation (SNP) | VAF 106/326 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61665402; called by muse, mutect2, varscan2
- LCN2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 103/388 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs546790138, COSV99478084; called by muse, varscan2
- LRFN5 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV53273998, COSV99985271; called by muse, mutect2, varscan2
- LRFN5 | c.1583C>A p.T528N | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184494599; called by muse, mutect2, varscan2
- LRP2 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 95/355 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.299); catalogued as COSV55539234; called by muse, mutect2, varscan2
- MAGI1 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 176/278 reads (63%) | catalogued as rs1380025378; called by muse, mutect2, varscan2
- MANEAL | c.788G>T p.S263I (on ENST00000373045 / NM_001113482.1; = p.S41I on NM_152496.2) | Missense Mutation (SNP) | VAF 358/358 reads (100%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs764965467; called by muse, mutect2, varscan2
- MARCHF4 | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 178/535 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV56102489; called by muse, mutect2, varscan2
- MAST4 | c.3178A>G p.S1060G (on ENST00000403625 / NM_001164664.2; = p.S871G on NM_015183.3) | Missense Mutation (SNP) | VAF 163/600 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1390610366; called by muse, mutect2, varscan2
- MDGA1 | c.2409C>A p.Y803* | Nonsense Mutation (SNP) | VAF 174/355 reads (49%) | catalogued as COSV99776627; called by muse, mutect2, varscan2
- MFSD4A | c.355A>G p.M119V | Missense Mutation (SNP) | VAF 166/983 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754380474; called by muse, mutect2, varscan2
- MICB | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 187/424 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.341); catalogued as rs769806725; called by muse, mutect2, varscan2
- MRGPRX4 | c.391C>A p.R131S | Missense Mutation (SNP) | VAF 386/386 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1170513963, COSV100049611, COSV58589672; called by muse, mutect2, varscan2
- MTARC2 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 75/528 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.173); catalogued as rs749638702; called by muse, mutect2, varscan2
- MYT1L | c.3089C>G p.P1030R | Missense Mutation (SNP) | VAF 271/365 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67704798; called by muse, mutect2, varscan2
- NAV3 | c.1199C>A p.P400Q | Missense Mutation (SNP) | VAF 124/496 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.829); catalogued as rs370224002, COSV57060374, COSV57084019; called by muse, mutect2, varscan2
- NIM1K | c.147G>C p.E49D | Missense Mutation (SNP) | VAF 147/566 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.463); catalogued as rs1197084630; called by muse, mutect2, varscan2
- NLGN4X | c.689C>A p.A230E | Missense Mutation (SNP) | VAF 168/310 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320532; called by muse, mutect2, varscan2
- NPAP1 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 46/362 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1391993692, COSV61506990; called by muse, mutect2, varscan2
- NPEPL1 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 117/444 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as COSV61938699; called by muse, mutect2, varscan2
- NPRL3 | c.494G>A p.R165Q (on ENST00000611875 / NM_001077350.3; = p.R140Q on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 272/613 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs770570210; called by muse, mutect2, varscan2
- NRAP | c.792C>G p.Y264* | Nonsense Mutation (SNP) | VAF 303/303 reads (100%) | catalogued as rs940017622; called by muse, mutect2, varscan2
- NRXN1 | c.4213G>T p.V1405F | Missense Mutation (SNP) | VAF 428/538 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV60511107; called by muse, mutect2, varscan2
- NSD3 | c.3869C>T p.S1290L | Missense Mutation (SNP) | VAF 68/956 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs377462564; called by muse, mutect2
- OPCML | c.1007C>A p.T336N | Missense Mutation (SNP) | VAF 112/541 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as rs772142837; called by muse, mutect2, varscan2
- OPRK1 | c.813G>T p.R271S | Missense Mutation (SNP) | VAF 262/382 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55571827; called by muse, mutect2, varscan2
- OR13C2 | c.859A>T p.M287L | Missense Mutation (SNP) | VAF 190/193 reads (98%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs142576527; called by muse, mutect2
- OR14A16 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 218/406 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62926054, COSV62926187; called by muse, mutect2, varscan2
- OR2L5 | c.23C>A p.S8* | Nonsense Mutation (SNP) | VAF 89/285 reads (31%) | catalogued as rs776623297; called by muse, mutect2, varscan2
- OR4A16 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 257/257 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.555); catalogued as COSV100125459; called by muse, mutect2, varscan2
- OR4C6 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 102/332 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV58603783; called by muse, mutect2, varscan2
- OR4D11 | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 125/399 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.151); catalogued as rs767524553; called by muse, mutect2, varscan2
- OR5AN1 | c.251C>A p.S84Y | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100004405; called by muse, mutect2, varscan2
- OR5J2 | c.431T>A p.L144H | Missense Mutation (SNP) | VAF 95/303 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56621412; called by muse, mutect2, varscan2
- OR5L2 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 349/349 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs267602980, COSV65723579; called by muse, mutect2, varscan2
- OR9I1 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 323/323 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs769620522, COSV56926317; called by muse, mutect2, varscan2
- PAK3 | c.1165G>T p.A389S (on ENST00000262836 / NM_001324328.2; = p.A374S on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/194 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53274698; called by muse, mutect2, varscan2
- PAPPA2 | c.5077G>T p.E1693* | Nonsense Mutation (SNP) | VAF 51/275 reads (19%) | catalogued as COSV62797726; called by muse, mutect2, varscan2
- PAPPA2 | c.5078A>T p.E1693V | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV62797059; called by muse, mutect2, varscan2
- PCDH11X | c.2386C>A p.P796T | Missense Mutation (SNP) | VAF 273/273 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV53460250; called by muse, mutect2, varscan2
- PCDH7 | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 413/545 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100687640; called by muse, mutect2, varscan2
- PCDHA3 | c.1449C>A p.D483E | Missense Mutation (SNP) | VAF 162/744 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1230044523, COSV63542712; called by muse, varscan2
- PCDHB5 | c.2164G>T p.G722C | Missense Mutation (SNP) | VAF 453/628 reads (72%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.942); catalogued as COSV50659658; called by muse, mutect2, varscan2
- PEX1 | c.796G>T p.G266C | Missense Mutation (SNP) | VAF 84/377 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV104373608; called by mutect2, varscan2
- PIAS4 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 151/480 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1442089986, COSV53679429; called by muse, mutect2, varscan2
- PLA2R1 | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 69/305 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV51776357, COSV99323534; called by muse, mutect2, varscan2
- PLCH1 | c.2885G>A p.R962H (on ENST00000340059 / NM_001130960.2; = p.R954H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/343 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs1010770122, COSV58193163; called by muse, mutect2, varscan2
- PLEKHD1 | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs760179013; called by muse, mutect2, varscan2
- PLPPR4 | c.2212C>A p.P738T | Missense Mutation (SNP) | VAF 338/338 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs768952470, COSV64567699; called by muse, mutect2, varscan2
- PLXND1 | c.3160C>T p.R1054W | Missense Mutation (SNP) | VAF 576/1115 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs761956464, COSV100138842; called by muse, varscan2
- PMEPA1 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 339/548 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55692105; called by muse, mutect2, varscan2
- PNPLA5 | c.1131G>T p.Q377H | Missense Mutation (SNP) | VAF 148/398 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV53374930; called by muse, mutect2, varscan2
- POLR2G | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 121/397 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.416); catalogued as COSV57135589; called by muse, mutect2, varscan2
- POTEF | c.1124C>A p.P375Q | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV62541349; called by muse, mutect2, varscan2
- PPP3CA | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 164/164 reads (100%) | catalogued as COSV100548062; called by muse, mutect2, varscan2
- PRR32 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 167/350 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV64420353; called by muse, mutect2, varscan2
- PRRX2 | c.466C>A p.R156S | Missense Mutation (SNP) | VAF 339/340 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65242046; called by muse, mutect2, varscan2
- PTPRD | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 434/434 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61928224, COSV61933453; called by muse, mutect2, varscan2
- PTPRQ | c.1974G>C p.Q658H (on ENST00000616559; = p.Q616H on NM_001145026.2) | Missense Mutation (SNP) | VAF 71/363 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as COSV99030928; called by muse, mutect2, varscan2
- RABGGTA | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 152/496 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs201173826; called by muse, mutect2, varscan2
- RAD51AP2 | c.3383G>A p.R1128K | Missense Mutation (SNP) | VAF 250/354 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs1314449454; called by muse, mutect2, varscan2
- REL | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 138/282 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs373752427; called by muse, mutect2, varscan2
- RENBP | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 418/418 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as rs782603882; called by muse, mutect2, varscan2
- RESP18 | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1325080974; called by muse, mutect2, varscan2
- RHOF | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 564/779 reads (72%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); catalogued as rs779872355, COSV57363257; called by muse, mutect2, varscan2
- RING1 | c.302C>G p.P101R | Missense Mutation (SNP) | VAF 165/751 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100761871; called by muse, mutect2, varscan2
- RNF181 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 200/298 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1342704126; called by muse, mutect2, varscan2
- RP1L1 | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 258/407 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.171); catalogued as rs377751683; called by muse, mutect2, varscan2
- RPGRIP1 | c.219G>T p.R73S | Missense Mutation (SNP) | VAF 114/326 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV52855920; called by muse, mutect2, varscan2
- RPS6KA2 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 90/272 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs749147718, COSV55826267, COSV99692157; called by muse, varscan2
- RPS6KC1 | c.1441C>G p.Q481E | Missense Mutation (SNP) | VAF 122/560 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as COSV65299372, COSV99055910; called by muse, mutect2, varscan2
- RUSC1 | c.1497del p.S500Rfs*20 (on ENST00000368352 / NM_001105203.2; = p.S31Rfs*20 on NM_014328.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 159/744 reads (21%) | catalogued as COSV52741180; called by mutect2, pindel, varscan2
- RYR2 | c.2018G>T p.W673L | Missense Mutation (SNP) | VAF 205/393 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757774138; called by muse, mutect2, varscan2
- RYR2 | c.7210C>A p.P2404T | Missense Mutation (SNP) | VAF 80/421 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318711262, CM097959, COSV100768063; called by muse, mutect2, varscan2
- SCN9A | c.5500G>A p.D1834N (on ENST00000303354; = p.D1823N on NM_002977.3) | Missense Mutation (SNP) | VAF 101/361 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV57608701; called by muse, mutect2, varscan2
- SCYL1 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 267/414 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs536228379; called by muse, mutect2, varscan2
- SELL | c.646C>T p.P216S (on ENST00000650983; = p.P203S on NM_000655.5) | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1052300235; called by muse, mutect2, varscan2
- SGCZ | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.202); catalogued as COSV66046658; called by muse, mutect2, varscan2
- SIGLEC11 | c.329del p.G110Afs*8 | Frame Shift Del (DEL) | VAF 64/313 reads (20%) | catalogued as COSV101389594; called by mutect2, varscan2
- SLC4A5 | c.1327G>A p.G443S | Missense Mutation (SNP) | VAF 219/621 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs776201138; called by muse, mutect2, varscan2
- SLC9A3R2 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 146/598 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs878958184, COSV54592691; called by muse, varscan2
- SLIT3 | c.4412C>T p.S1471F | Missense Mutation (SNP) | VAF 155/534 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs956212203; called by muse, mutect2, varscan2
- SMARCAL1 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 154/228 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs771595818; called by muse, mutect2, varscan2
- SMARCB1 | c.562G>T p.V188L (on ENST00000263121; = p.V234L on NM_003073.5) | Missense Mutation (SNP) | VAF 244/463 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.363); catalogued as rs1272912695; called by muse, mutect2, varscan2
- ST8SIA5 | c.606G>T p.M202I | Missense Mutation (SNP) | VAF 183/402 reads (46%) | PolyPhen benign (0.03); catalogued as COSV100164536, COSV59335365; called by muse, mutect2, varscan2
- STAB1 | c.6442G>T p.A2148S | Missense Mutation (SNP) | VAF 118/416 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58732684; called by muse, mutect2, varscan2
- STK36 | c.3773G>C p.R1258P | Missense Mutation (SNP) | VAF 226/333 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99831756; called by muse, mutect2, varscan2
- STMN2 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 281/649 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV55221171, COSV99627078; called by muse, mutect2, varscan2
- TAFA5 | c.316G>A p.E106K (on ENST00000402357 / NM_001082967.3; = p.E99K on NM_015381.7) | Missense Mutation (SNP) | VAF 102/353 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60992616; called by muse, mutect2, varscan2
- TBC1D9 | c.2929G>T p.G977C | Missense Mutation (SNP) | VAF 82/298 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101464346; called by mutect2, varscan2
- TBKBP1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 301/463 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64654129; called by muse, mutect2, varscan2
- TEP1 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 112/430 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs751721420; called by muse, mutect2, varscan2
- TGIF2LX | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 279/280 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99383308; called by muse, mutect2, varscan2
- THSD7B | c.2167C>T p.R723* | Nonsense Mutation (SNP) | VAF 66/132 reads (50%) | catalogued as rs1337933182, COSV55649817, COSV99757072; called by muse, mutect2, varscan2
- TLL1 | c.2110C>T p.Q704* | Nonsense Mutation (SNP) | VAF 236/236 reads (100%) | catalogued as COSV99288686; called by muse, mutect2, varscan2
- TMEM143 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 161/778 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs143728408; called by muse, mutect2, varscan2
- TMEM244 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 61/287 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as COSV63743261; called by muse, mutect2, varscan2
- TMEM71 | c.438C>A p.N146K (on ENST00000523829 / NM_001382398.1; = p.N127K on NM_144649.3) | Missense Mutation (SNP) | VAF 201/599 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100785575, COSV63457207; called by muse, mutect2, varscan2
- TRIM22 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 294/294 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs372042006, COSV66090849; called by muse, mutect2, varscan2
- TRIM69 | c.772C>A p.Q258K (on ENST00000329464 / NM_182985.5; = p.Q99K on NM_080745.5) | Missense Mutation (SNP) | VAF 121/399 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs779421211; called by muse, mutect2, varscan2
- TRIM9 | c.272C>A p.P91Q | Missense Mutation (SNP) | VAF 175/578 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as COSV53621044; called by muse, mutect2, varscan2
- TRPV3 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 297/297 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs375812083; called by muse, mutect2, varscan2
- TTN | c.94099C>A p.L31367I (on ENST00000591111; = p.L23943I on NM_003319.4) | Missense Mutation (SNP) | VAF 91/276 reads (33%) | PolyPhen benign (0.011); catalogued as COSV59968190; called by muse, mutect2, varscan2
- TTN | c.76283C>A p.P25428Q (on ENST00000591111; = p.P18004Q on NM_003319.4) | Missense Mutation (SNP) | VAF 138/382 reads (36%) | PolyPhen possibly damaging (0.758); catalogued as COSV59907409, COSV60082814; called by muse, mutect2, varscan2
- TTN | c.67220G>T p.R22407I (on ENST00000591111; = p.R14983I on NM_003319.4) | Missense Mutation (SNP) | VAF 142/455 reads (31%) | PolyPhen benign (0.186); catalogued as COSV59863511; called by muse, mutect2, varscan2
- TUT4 | c.1634G>T p.W545L | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV57115833; called by muse, varscan2
- TXNRD1 | c.419A>G p.Y140C (on ENST00000525566 / NM_001093771.3; = p.Y42C on NM_003330.4) | Missense Mutation (SNP) | VAF 59/253 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as rs1306122055; called by muse, mutect2, varscan2
- UBA52 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 376/376 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.317); catalogued as COSV70615424; called by muse, mutect2, varscan2
- UGT2B11 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1346195724; called by muse, mutect2, varscan2
- UNC13C | c.5653G>T p.A1885S | Missense Mutation (SNP) | VAF 123/195 reads (63%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.985); catalogued as COSV52845480; called by muse, mutect2, varscan2
- UNC80 | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 127/414 reads (31%) | catalogued as COSV99778591; called by muse, mutect2, varscan2
- USH2A | c.2553G>T p.K851N | Missense Mutation (SNP) | VAF 65/496 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.139); catalogued as rs781117624; called by muse, varscan2
- VCAN | c.3257G>C p.R1086T | Missense Mutation (SNP) | VAF 318/440 reads (72%) | SIFT tolerated (0.15); PolyPhen benign (0.236); catalogued as COSV54113044; called by muse, mutect2, varscan2
- VCAN | c.4337G>T p.S1446I | Missense Mutation (SNP) | VAF 332/444 reads (75%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.757); catalogued as rs764331111; called by muse, varscan2
- VCAN | c.7572C>A p.F2524L | Missense Mutation (SNP) | VAF 219/290 reads (76%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV54096118; called by mutect2, varscan2
- VCAN | c.7573A>G p.R2525G | Missense Mutation (SNP) | VAF 219/290 reads (76%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV54111358; called by mutect2, varscan2
- VIPAS39 | c.575A>G p.H192R | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs939430612; called by muse, mutect2, varscan2
- VIPR1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 375/509 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs766398547; called by muse, mutect2, varscan2
- XIRP2 | c.5985G>T p.M1995I (on ENST00000628543; = p.M2170I on NM_152381.6) | Missense Mutation (SNP) | VAF 109/356 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54737398; called by muse, mutect2, varscan2
- XIRP2 | c.8740G>A p.E2914K (on ENST00000628543; = p.E3089K on NM_152381.6) | Missense Mutation (SNP) | VAF 233/342 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as rs1251526612; called by muse, mutect2, varscan2
- XRN1 | c.4691G>T p.G1564V | Missense Mutation (SNP) | VAF 323/591 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); catalogued as rs960789057; called by muse, mutect2, varscan2
- YTHDC2 | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs1310660928; called by muse, mutect2, varscan2
- ZBTB42 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 274/423 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs919456705, COSV61137132; called by muse, mutect2, varscan2
- ZDHHC17 | c.1668A>G p.I556M | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1187458926; called by muse, mutect2, varscan2
- ZFHX3 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 138/495 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV51721237; called by muse, mutect2, varscan2
- ZFHX4 | c.1793C>G p.P598R | Missense Mutation (SNP) | VAF 341/716 reads (48%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.79); catalogued as COSV99264243; called by muse, mutect2, varscan2
- ZNF142 | c.1234C>T p.R412W (on ENST00000411696 / NM_001379660.1; = p.R212W on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 171/511 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1275178693; called by muse, mutect2, varscan2
- ZNF221 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 85/377 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746568984; called by muse, mutect2, varscan2
- ZNF248 | c.907G>T p.G303W | Missense Mutation (SNP) | VAF 294/295 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs75080219; called by muse, mutect2, varscan2
- ZNF385D | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 298/298 reads (100%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs1254145219; called by muse, mutect2, varscan2
- ZNF534 | c.1394C>T p.S465F (on ENST00000332323 / NM_001143939.3; = p.S452F on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 215/440 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0.046); catalogued as rs1408645488, COSV56517257; called by muse, mutect2, varscan2
- ZNF600 | c.1484A>G p.E495G | Missense Mutation (SNP) | VAF 321/453 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs1385771192; called by muse, mutect2, varscan2
- ZNF804A | c.1375C>A p.P459T | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56467272; called by muse, mutect2, varscan2
- ZNF804B | c.1907A>T p.K636M | Missense Mutation (SNP) | VAF 215/276 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV60823083; called by muse, mutect2, varscan2
- ABCA13 | c.14570A>T p.Y4857F | Missense Mutation (SNP) | VAF 178/273 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCD3 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 84/255 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ABHD12 | c.1121A>G p.Y374C | Missense Mutation (SNP) | VAF 209/428 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ABHD16A | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 186/808 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABHD18 | c.895G>C p.D299H (on ENST00000398965 / NM_001039717.2; = p.D206H on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/235 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ABTB2 | c.574G>C p.G192R | Missense Mutation (SNP) | VAF 596/598 reads (100%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AC099489.1 | c.6380G>T p.W2127L | Missense Mutation (SNP) | VAF 146/586 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, mutect2
- ACSM2B | c.125C>A p.A42D | Missense Mutation (SNP) | VAF 247/415 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ACTL9 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 506/506 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTRT2 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 109/313 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ADAM18 | c.1925G>T p.C642F | Missense Mutation (SNP) | VAF 179/249 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ADAM20 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 118/346 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ADAM23 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 101/341 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS6 | c.2650G>T p.D884Y | Missense Mutation (SNP) | VAF 85/382 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ADAMTSL1 | c.3694G>T p.D1232Y | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ADCY2 | c.3182G>A p.G1061E | Missense Mutation (SNP) | VAF 362/480 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY8 | c.1110G>T p.Q370H | Missense Mutation (SNP) | VAF 60/363 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ADGB | c.379A>G p.N127D | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ADGRB3 | c.3455G>T p.R1152I | Missense Mutation (SNP) | VAF 87/189 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ADGRF4 | c.553-1G>A p.X185_splice | Splice Site (SNP) | VAF 58/286 reads (20%) | called by muse, mutect2, varscan2
- ADGRG7 | c.1070A>T p.Q357L | Missense Mutation (SNP) | VAF 196/465 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADGRL2 | c.2183G>T p.S728I (on ENST00000370717 / NM_001366005.1; = p.S715I on NM_012302.4) | Missense Mutation (SNP) | VAF 264/264 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ADGRL2 | c.4231C>G p.P1411A (on ENST00000370717 / NM_001366005.1; = p.P1355A on NM_012302.4) | Missense Mutation (SNP) | VAF 262/263 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADGRL3 | c.4635C>A p.Y1545* (on ENST00000506720 / NM_001322402.2; = p.Y1434* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 216/217 reads (100%) | called by muse, mutect2, varscan2
- ADGRL3 | c.4636C>A p.Q1546K (on ENST00000506720 / NM_001322402.2; = p.Q1435K on NM_015236.6) | Missense Mutation (SNP) | VAF 218/218 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- AGAP2 | c.3373C>A p.R1125S (on ENST00000547588 / NM_001122772.2; = p.R769S on NM_014770.4) | Missense Mutation (SNP) | VAF 338/1167 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- AHNAK2 | c.14309C>T p.S4770F | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- AHNAK2 | c.6376C>A p.P2126T | Missense Mutation (SNP) | VAF 153/476 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, varscan2
- AK9 | c.4238G>A p.R1413K | Missense Mutation (SNP) | VAF 165/343 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKT2 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 245/360 reads (68%) | called by muse, mutect2, varscan2
- AKT2 | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 439/600 reads (73%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK1 | c.3787G>T p.D1263Y | Missense Mutation (SNP) | VAF 255/410 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ANKRD22 | c.29G>T p.C10F | Missense Mutation (SNP) | VAF 158/158 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD34C | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 210/327 reads (64%) | SIFT tolerated (0.5); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ANKRD60 | c.116G>C p.S39T | Missense Mutation (SNP) | VAF 157/474 reads (33%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- APBA2 | c.1849C>A p.Q617K | Missense Mutation (SNP) | VAF 407/601 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- APBB1IP | c.611T>A p.L204Q | Missense Mutation (SNP) | VAF 398/398 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- APC | c.6824A>T p.K2275M | Missense Mutation (SNP) | VAF 107/531 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- APOB | c.496G>T p.V166F | Missense Mutation (SNP) | VAF 257/387 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- ARHGAP39 | c.785A>G p.D262G | Missense Mutation (SNP) | VAF 156/1015 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ARHGEF25 | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 161/670 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ARID5B | c.3142G>T p.E1048* | Nonsense Mutation (SNP) | VAF 118/403 reads (29%) | called by muse, mutect2, varscan2
- ARNT2 | c.923A>C p.K308T | Missense Mutation (SNP) | VAF 177/271 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ARSK | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 150/212 reads (71%) | called by muse, mutect2, varscan2
- ASPRV1 | c.13G>T p.G5W | Missense Mutation (SNP) | VAF 120/332 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ATG14 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP6V0A2 | c.2084G>A p.S695N | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AUTS2 | c.1235_1246del p.P412_T415del | In Frame Del (DEL) | VAF 40/297 reads (13%) | called by mutect2, pindel, varscan2
- AUTS2 | c.1436_1438del p.V479del | In Frame Del (DEL) | VAF 100/403 reads (25%) | called by mutect2, pindel, varscan2
- B4GALNT3 | c.2609A>T p.D870V | Missense Mutation (SNP) | VAF 140/225 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BABAM2 | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 107/381 reads (28%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BARHL2 | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 528/532 reads (99%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- BCHE | c.519C>A p.N173K | Missense Mutation (SNP) | VAF 306/681 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BHLHE41 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 154/471 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- BNC2 | c.1301C>A p.S434* | Nonsense Mutation (SNP) | VAF 137/137 reads (100%) | called by muse, mutect2, varscan2
- BPIFB4 | c.548T>C p.I183T | Missense Mutation (SNP) | VAF 83/611 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- C15orf39 | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 171/594 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C1QTNF7 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 394/503 reads (78%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- C4BPA | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 277/456 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- C7 | c.1364G>T p.C455F | Missense Mutation (SNP) | VAF 278/390 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1D | c.3979G>T p.V1327L (on ENST00000350061 / NM_001128840.3; = p.V1347L on NM_000720.4) | Missense Mutation (SNP) | VAF 293/293 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CACNA1E | c.6324G>T p.Q2108H (on ENST00000367573 / NM_001205293.3; = p.Q2065H on NM_000721.4) | Missense Mutation (SNP) | VAF 210/433 reads (48%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- CADM2 | c.649G>T p.A217S (on ENST00000407528 / NM_001167674.2; = p.A219S on NM_153184.4) | Missense Mutation (SNP) | VAF 241/241 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- CAMK2B | c.863T>A p.V288E | Missense Mutation (SNP) | VAF 140/448 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPRIN2 | c.842A>T p.Y281F | Missense Mutation (SNP) | VAF 256/382 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- CARD6 | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 114/368 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by mutect2, varscan2
- CARMIL2 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 95/473 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCDC15 | c.1439dup p.L480Ffs*3 | Frame Shift Ins (INS) | VAF 80/570 reads (14%) | called by pindel, varscan2
- CCDC178 | c.1039C>T p.L347F | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CCDC27 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 444/445 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- CCL8 | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 177/268 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CCT8L2 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 114/228 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CDC42BPA | c.777T>A p.Y259* | Nonsense Mutation (SNP) | VAF 89/559 reads (16%) | called by muse, mutect2, varscan2
- CDH11 | c.591A>T p.L197F | Missense Mutation (SNP) | VAF 75/351 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH19 | c.1145A>G p.E382G | Missense Mutation (SNP) | VAF 208/445 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2
- CDH23 | c.690G>C p.Q230H | Missense Mutation (SNP) | VAF 419/420 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CELF3 | c.9G>T p.E3D | Missense Mutation (SNP) | VAF 110/486 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CFAP69 | c.548G>T p.S183I | Missense Mutation (SNP) | VAF 187/266 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- CHD6 | c.6458G>T p.G2153V | Missense Mutation (SNP) | VAF 204/345 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- CHRM2 | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 93/434 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CHST3 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 619/620 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CHSY3 | c.2544G>T p.K848N | Missense Mutation (SNP) | VAF 105/393 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CHUK | c.857A>T p.Q286L | Missense Mutation (SNP) | VAF 389/389 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CIR1 | c.1011G>C p.R337S | Missense Mutation (SNP) | VAF 109/340 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, varscan2
- CLEC1A | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 158/224 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CNDP2 | c.952G>T p.G318C | Missense Mutation (SNP) | VAF 101/498 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNGB3 | c.1391C>A p.A464D | Missense Mutation (SNP) | VAF 111/761 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTNAP3 | c.3106A>T p.T1036S | Missense Mutation (SNP) | VAF 85/776 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, varscan2
- COL14A1 | c.3035C>G p.P1012R | Missense Mutation (SNP) | VAF 201/598 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL14A1 | c.5376G>C p.W1792C | Missense Mutation (SNP) | VAF 273/526 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- COL20A1 | c.3606C>A p.S1202R | Missense Mutation (SNP) | VAF 220/390 reads (56%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- COL21A1 | c.2172G>T p.Q724H | Missense Mutation (SNP) | VAF 115/219 reads (53%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- COL24A1 | c.1707G>T p.K569N | Missense Mutation (SNP) | VAF 243/243 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- COL2A1 | c.3445G>T p.G1149* | Nonsense Mutation (SNP) | VAF 348/491 reads (71%) | called by muse, mutect2, varscan2
- COL3A1 | c.2966G>T p.S989I | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- COL4A2 | c.985G>T p.G329W | Missense Mutation (SNP) | VAF 392/393 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A2 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 364/364 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- COL4A2 | c.2686G>T p.G896W | Missense Mutation (SNP) | VAF 134/410 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COL6A5 | c.1736G>A p.G579E | Missense Mutation (SNP) | VAF 337/631 reads (53%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- COL6A5 | c.3773C>A p.A1258D | Missense Mutation (SNP) | VAF 266/590 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.347); called by mutect2, varscan2
- COL6A5 | c.5426G>C p.G1809A (on ENST00000312481; = p.G1805A on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 309/702 reads (44%) | SIFT tolerated (0.78); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- COL7A1 | c.8175_8192del p.P2727_P2732del | In Frame Del (DEL) | VAF 219/226 reads (97%) | called by mutect2, pindel, varscan2
- CORO2A | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 352/352 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CR2 | c.2333A>T p.Q778L | Missense Mutation (SNP) | VAF 436/741 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CRACD | c.2641_2642insA p.A881Dfs*42 | Frame Shift Ins (INS) | VAF 134/433 reads (31%) | called by mutect2, pindel*, varscan2
- CRISPLD1 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 97/594 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CROT | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRPPA | c.938T>A p.V313E (on ENST00000407010 / NM_001368197.1; = p.V263E on NM_001101417.4) | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CRYBG1 | c.2032G>T p.A678S | Missense Mutation (SNP) | VAF 177/400 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.6890C>A p.P2297H (on ENST00000297405 / NM_001363185.1; = p.P2193H on NM_052900.3) | Missense Mutation (SNP) | VAF 236/584 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.4427C>A p.P1476Q (on ENST00000297405 / NM_001363185.1; = p.P1372Q on NM_052900.3) | Missense Mutation (SNP) | VAF 255/579 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- CSMD3 | c.4361+1G>T p.X1454_splice (on ENST00000297405 / NM_001363185.1; = p.X1350_splice on NM_052900.3) | Splice Site (SNP) | VAF 122/236 reads (52%) | called by muse, mutect2, varscan2
- CSMD3 | c.4361G>C p.S1454T (on ENST00000297405 / NM_001363185.1; = p.S1350T on NM_052900.3) | Missense Mutation (SNP) | VAF 124/242 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CSMD3 | c.3868C>A p.Q1290K (on ENST00000297405 / NM_001363185.1; = p.Q1186K on NM_052900.3) | Missense Mutation (SNP) | VAF 130/316 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CSMD3 | c.2091dup p.G698Wfs*11 (on ENST00000297405 / NM_001363185.1; = p.G594Wfs*11 on NM_052900.3) | Frame Shift Ins (INS) | VAF 222/691 reads (32%) | called by mutect2, pindel, varscan2
- CSNKA2IP | c.1834T>C p.S612P | Missense Mutation (SNP) | VAF 337/337 reads (100%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTNNA2 | c.2536G>A p.G846R | Missense Mutation (SNP) | VAF 131/248 reads (53%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTSZ | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 294/526 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CUX1 | c.2327C>G p.S776C | Missense Mutation (SNP) | VAF 188/844 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- CYFIP2 | c.1286G>C p.G429A | Missense Mutation (SNP) | VAF 104/401 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- CYREN | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 104/494 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- D2HGDH | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 136/444 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DBX2 | c.587A>T p.D196V | Missense Mutation (SNP) | VAF 333/471 reads (71%) | SIFT tolerated (0.28); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- DCC | c.613_614insT p.G205Vfs*21 | Frame Shift Ins (INS) | VAF 169/475 reads (36%) | called by mutect2, pindel, varscan2
- DDX1 | c.1283G>C p.W428S | Missense Mutation (SNP) | VAF 250/340 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DENND5A | c.2038A>T p.T680S | Missense Mutation (SNP) | VAF 92/304 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- DGCR2 | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 114/229 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- DGKI | c.1954dup p.L652Pfs*34 | Frame Shift Ins (INS) | VAF 62/320 reads (19%) | called by mutect2, pindel, varscan2
- DGKQ | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 142/891 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHCR7 | c.827T>C p.L276P | Missense Mutation (SNP) | VAF 292/293 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHRS7C | c.241T>G p.L81V | Missense Mutation (SNP) | VAF 215/218 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DLX6 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 110/536 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DNAH5 | c.8416A>T p.N2806Y | Missense Mutation (SNP) | VAF 221/289 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- DNAH7 | c.5198C>T p.P1733L | Missense Mutation (SNP) | VAF 187/252 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DNAH9 | c.11846C>T p.A3949V | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DPPA4 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 354/799 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- DPY19L3 | c.1883G>A p.R628K | Missense Mutation (SNP) | VAF 106/427 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DSC3 | c.731C>A p.T244K | Missense Mutation (SNP) | VAF 139/320 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- DSG1 | c.2010A>C p.Q670H | Missense Mutation (SNP) | VAF 65/334 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- DUOX2 | c.2353G>T p.A785S | Missense Mutation (SNP) | VAF 134/387 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DUSP10 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 105/585 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EDEM3 | c.2167A>G p.I723V | Missense Mutation (SNP) | VAF 120/486 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EEF1A2 | c.1322T>C p.V441A | Missense Mutation (SNP) | VAF 127/341 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- EEPD1 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 187/295 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EFCC1 | c.1696C>G p.L566V | Missense Mutation (SNP) | VAF 346/1238 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EGFR | c.89-1G>T p.X30_splice | Splice Site (SNP) | VAF 67/243 reads (28%) | called by muse, mutect2, varscan2
- EGFR | c.2793A>T p.E931D | Missense Mutation (SNP) | VAF 75/352 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ELMO1 | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 75/232 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ENTPD2 | c.674A>T p.Q225L | Missense Mutation (SNP) | VAF 731/731 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- EPB41L3 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 373/751 reads (50%) | called by muse, mutect2, varscan2
- EPHA5 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 85/177 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- EPHA7 | c.1938A>T p.E646D | Missense Mutation (SNP) | VAF 125/248 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ESR1 | c.1115T>A p.L372H | Missense Mutation (SNP) | VAF 145/314 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EVC | c.1785G>T p.M595I | Missense Mutation (SNP) | VAF 466/602 reads (77%) | SIFT tolerated (0.33); PolyPhen benign (0.085); called by muse, mutect2
- EVC2 | c.221G>T p.S74I | Missense Mutation (SNP) | VAF 92/534 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC3L4 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 130/451 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- FANCM | c.315C>A p.C105* | Nonsense Mutation (SNP) | VAF 120/429 reads (28%) | called by muse, mutect2, varscan2
- FANK1 | c.447G>T p.M149I | Missense Mutation (SNP) | VAF 496/496 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FAP | c.989G>T p.W330L | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FASTKD5 | c.1659G>T p.M553I | Missense Mutation (SNP) | VAF 270/416 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- FAT2 | c.10438G>C p.D3480H | Missense Mutation (SNP) | VAF 106/497 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- FBN1 | c.3398A>C p.E1133A | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- FBN2 | c.5012G>T p.G1671V | Missense Mutation (SNP) | VAF 299/412 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- FBXO5 | c.321A>T p.Q107H | Missense Mutation (SNP) | VAF 170/375 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FCRL3 | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 147/549 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FCRL3 | c.701C>A p.T234N | Missense Mutation (SNP) | VAF 109/530 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- FGG | c.1350G>T p.E450D | Missense Mutation (SNP) | VAF 158/158 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, varscan2
- FMN1 | c.2442G>C p.K814N (on ENST00000616417 / NM_001277313.2; = p.K591N on NM_001103184.4) | Missense Mutation (SNP) | VAF 203/319 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- FOXN4 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 132/584 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXP2 | c.1493A>T p.Y498F | Missense Mutation (SNP) | VAF 172/242 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- FSCN3 | c.1138G>T p.G380W | Missense Mutation (SNP) | VAF 240/334 reads (72%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- FSIP2 | c.1073C>A p.T358K | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FSIP2 | c.9517G>T p.E3173* | Nonsense Mutation (SNP) | VAF 166/272 reads (61%) | called by muse, mutect2, varscan2
- FXR1 | c.1605C>T p.V535= | Splice Region (SNP) | VAF 153/344 reads (44%) | called by muse, mutect2, varscan2
- FZD5 | c.403C>A p.R135S | Missense Mutation (SNP) | VAF 217/725 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FZD5 | c.402C>A p.D134E | Missense Mutation (SNP) | VAF 217/724 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GABRA2 | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 74/382 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GABRG1 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 237/306 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GABRG3 | c.667T>A p.F223I | Missense Mutation (SNP) | VAF 99/341 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- GADD45A | c.87del p.A30Pfs*2 | Frame Shift Del (DEL) | VAF 191/641 reads (30%) | called by mutect2, pindel, varscan2
- GATA5 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 238/433 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GATB | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 101/101 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDF2 | c.737C>A p.P246Q | Missense Mutation (SNP) | VAF 403/403 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- GEMIN5 | c.3086G>C p.W1029S | Missense Mutation (SNP) | VAF 114/446 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GGT1 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 134/346 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GIN1 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 58/309 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GJE1 | c.209C>A p.P70Q | Missense Mutation (SNP) | VAF 121/257 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GLB1L3 | c.1408C>A p.H470N | Missense Mutation (SNP) | VAF 82/472 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GLIPR1L2 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 63/269 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- GLRA3 | c.712+1G>T p.X238_splice | Splice Site (SNP) | VAF 105/106 reads (99%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.1904C>A p.A635E | Missense Mutation (SNP) | VAF 164/712 reads (23%) | SIFT deleterious, low confidence (0); called by muse, varscan2
- GPATCH2 | c.1400A>C p.E467A | Missense Mutation (SNP) | VAF 260/442 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2
- GPC6 | c.558C>A p.Y186* | Nonsense Mutation (SNP) | VAF 120/323 reads (37%) | called by muse, varscan2
- GPD2 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 118/354 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRAMD1C | c.772G>T p.G258* | Nonsense Mutation (SNP) | VAF 176/400 reads (44%) | called by muse, mutect2, varscan2
- GRIN3A | c.1409A>T p.H470L | Missense Mutation (SNP) | VAF 269/269 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTF2I | c.1258G>T p.E420* (on ENST00000573035 / NM_032999.4; = p.E379* on NM_001518.5) | Nonsense Mutation (SNP) | VAF 67/340 reads (20%) | called by muse, mutect2, varscan2
- GTF2IRD1 | c.1566G>T p.M522I | Missense Mutation (SNP) | VAF 99/432 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GZMB | c.712C>G p.H238D | Missense Mutation (SNP) | VAF 96/332 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2BW1 | c.201T>G p.H67Q | Missense Mutation (SNP) | VAF 275/275 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- HAGH | c.383A>C p.D128A | Missense Mutation (SNP) | VAF 161/703 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- HDAC11 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 86/418 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- HECW2 | c.3536A>T p.Q1179L | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- HERC2 | c.1732G>T p.G578W | Missense Mutation (SNP) | VAF 304/439 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HHLA1 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 119/703 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HK3 | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 210/881 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- HMX3 | c.261G>T p.Q87H | Missense Mutation (SNP) | VAF 713/720 reads (99%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- HOXA4 | c.587C>A p.P196H | Missense Mutation (SNP) | VAF 211/336 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HOXA4 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 217/342 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- HRG | c.736C>G p.P246A | Missense Mutation (SNP) | VAF 35/355 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IBTK | c.1156G>T p.G386W | Missense Mutation (SNP) | VAF 121/292 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFRD1 | c.1097A>T p.D366V | Missense Mutation (SNP) | VAF 192/285 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGF2R | c.6716C>T p.S2239F | Missense Mutation (SNP) | VAF 250/450 reads (56%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGFN1 | c.2153G>T p.R718L (on ENST00000295591 / NM_001367841.1; = p.R3175L on NM_001164586.2) | Missense Mutation (SNP) | VAF 155/616 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- IGLV2-14 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 112/237 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- IGLV7-46 | c.91G>T p.V31L | Missense Mutation (SNP) | VAF 105/226 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IGSF21 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 280/282 reads (99%) | called by muse, mutect2, varscan2
- IL19 | c.86T>G p.L29R | Missense Mutation (SNP) | VAF 96/562 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- IL1RAP | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 200/396 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- IL7R | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 214/288 reads (74%) | called by muse, mutect2, varscan2
- INPP5J | c.524del p.G175Dfs*11 | Frame Shift Del (DEL) | VAF 365/717 reads (51%) | called by mutect2, pindel, varscan2
- INSM2 | c.706G>C p.V236L | Missense Mutation (SNP) | VAF 358/556 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- IPO8 | c.2929C>T p.Q977* | Nonsense Mutation (SNP) | VAF 213/295 reads (72%) | called by muse, mutect2, varscan2
- IRAK4 | c.890A>T p.N297I | Missense Mutation (SNP) | VAF 152/341 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ITIH1 | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 354/354 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITIH6 | c.2779C>G p.L927V | Missense Mutation (SNP) | VAF 333/333 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ITPR3 | c.3157_3158delinsT p.R1053Sfs*46 | Frame Shift Del (DEL) | VAF 284/987 reads (29%) | called by pindel, varscan2*
- ITPR3 | c.6781A>G p.I2261V | Missense Mutation (SNP) | VAF 181/820 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- JMJD4 | c.510G>C p.Q170H | Missense Mutation (SNP) | VAF 174/879 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- JPH2 | c.1787C>A p.P596H | Missense Mutation (SNP) | VAF 319/545 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- KAT6A | c.5191A>G p.I1731V | Missense Mutation (SNP) | VAF 260/382 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- KATNIP | c.4757A>G p.Q1586R | Missense Mutation (SNP) | VAF 261/381 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- KCNA10 | c.1240T>A p.W414R | Missense Mutation (SNP) | VAF 414/414 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCND2 | c.1352G>T p.G451V | Missense Mutation (SNP) | VAF 72/334 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- KDM4E | c.1128C>A p.N376K | Missense Mutation (SNP) | VAF 127/523 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KEAP1 | c.544del p.S182Afs*48 | Frame Shift Del (DEL) | VAF 452/625 reads (72%) | called by mutect2, pindel, varscan2
- KHDRBS3 | c.976C>A p.H326N | Missense Mutation (SNP) | VAF 83/491 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF1A | c.2848G>C p.G950R | Missense Mutation (SNP) | VAF 197/645 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KIF20A | c.2089C>G p.Q697E | Missense Mutation (SNP) | VAF 86/400 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF25 | c.756del p.N253Tfs*29 (on ENST00000354419 / NM_030615.2; = p.N253Tfs*32 on NM_005355.3) | Frame Shift Del (DEL) | VAF 346/646 reads (54%) | called by mutect2, pindel, varscan2
- KIF7 | c.3448G>C p.D1150H | Missense Mutation (SNP) | VAF 375/620 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIR2DL3 | c.284C>G p.A95G | Missense Mutation (SNP) | VAF 85/372 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KIR3DL1 | c.335C>A p.P112H | Missense Mutation (SNP) | VAF 44/291 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KLHL1 | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 258/258 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- KMO | c.1016G>T p.S339I | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.097); called by mutect2, varscan2
- KMT2A | c.886G>T p.G296W | Missense Mutation (SNP) | VAF 421/422 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KRBA1 | c.1311A>T p.R437S | Missense Mutation (SNP) | VAF 106/459 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- KRT6A | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 250/378 reads (66%) | called by muse, varscan2
- KRT72 | c.1496C>T p.T499I | Missense Mutation (SNP) | VAF 109/492 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- KRTAP11-1 | c.47G>C p.G16A | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- LACTB | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 262/795 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2
- LAD1 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 97/378 reads (26%) | called by muse, mutect2, varscan2
- LAMA4 | c.2884A>G p.K962E (on ENST00000230538 / NM_001105206.3; = p.K955E on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/545 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LCTL | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 110/374 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by mutect2, varscan2
- LEFTY1 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 170/904 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- LGR5 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 86/347 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LHCGR | c.1995T>A p.N665K | Missense Mutation (SNP) | VAF 103/460 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- LIX1 | c.341A>G p.K114R | Missense Mutation (SNP) | VAF 83/399 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LNPEP | c.428A>G p.K143R | Missense Mutation (SNP) | VAF 218/468 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by mutect2, varscan2
- LRATD1 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 496/633 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- LRGUK | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 81/380 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRP4 | c.1683G>T p.L561F | Missense Mutation (SNP) | VAF 254/254 reads (100%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRRC4B | c.239T>A p.V80D | Missense Mutation (SNP) | VAF 154/669 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRRC9 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 210/380 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRN1 | c.739T>A p.Y247N | Missense Mutation (SNP) | VAF 93/473 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LRRTM1 | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 219/361 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LTBP2 | c.3651G>A p.Q1217= | Splice Region (SNP) | VAF 119/302 reads (39%) | called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.208C>A p.H70N | Missense Mutation (SNP) | VAF 123/772 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MAGEL2 | c.1420C>A p.Q474K | Missense Mutation (SNP) | VAF 244/702 reads (35%) | SIFT tolerated, low confidence (0.9); called by muse, mutect2, varscan2
- MAMDC2 | c.774C>A p.D258E | Missense Mutation (SNP) | VAF 434/434 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- MAP3K20 | c.1088T>C p.V363A | Missense Mutation (SNP) | VAF 87/299 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARCOL | c.206C>A p.T69K | Missense Mutation (SNP) | VAF 244/355 reads (69%) | SIFT tolerated (0.73); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MBD2 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 198/350 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDGA1 | c.1630_1635del p.S544_S545del | In Frame Del (DEL) | VAF 268/629 reads (43%) | called by mutect2, pindel, varscan2
- MDN1 | c.9302G>T p.W3101L | Missense Mutation (SNP) | VAF 154/324 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- MEF2C | c.1079C>A p.P360Q | Missense Mutation (SNP) | VAF 234/314 reads (75%) | SIFT tolerated (0.43); PolyPhen benign (0.103); called by mutect2, varscan2
- MGAM | c.2948G>C p.C983S | Missense Mutation (SNP) | VAF 157/322 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIA3 | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 173/1056 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MLLT3 | c.376A>C p.N126H | Missense Mutation (SNP) | VAF 149/149 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MN1 | c.1877C>A p.A626E | Missense Mutation (SNP) | VAF 167/524 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MOB3B | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 183/327 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOCOS | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 186/410 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MRC1 | c.2779A>T p.S927C | Missense Mutation (SNP) | VAF 389/389 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- MRGPRG | c.656G>T p.S219I | Missense Mutation (SNP) | VAF 492/492 reads (100%) | SIFT tolerated (0.42); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- MROH5 | c.2530C>A p.L844M | Missense Mutation (SNP) | VAF 354/1010 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MRPS7 | c.128A>T p.D43V | Missense Mutation (SNP) | VAF 157/488 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- MRPS9 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- MUC5B | c.11030C>A p.T3677N | Missense Mutation (SNP) | VAF 637/676 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- MYO18B | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 260/377 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYRFL | c.2272G>T p.D758Y | Missense Mutation (SNP) | VAF 305/403 reads (76%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NACAD | c.3686C>A p.P1229H | Missense Mutation (SNP) | VAF 169/557 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- NAPA | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 112/438 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NAV3 | c.6150C>A p.H2050Q (on ENST00000397909 / NM_001024383.2; = p.H2028Q on NM_014903.6) | Missense Mutation (SNP) | VAF 289/384 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- NCAPD3 | c.2237+1G>T p.X746_splice | Splice Site (SNP) | VAF 263/343 reads (77%) | called by muse, mutect2, varscan2
- NECTIN3 | c.1089_1110delinsTGACTGTGCTGCTGACTCCTCG p.T364_R370delinsDCAADSS | Missense Mutation (ONP) | VAF 81/812 reads (10%) | called by mutect2*, pindel, varscan2*
- NEXMIF | c.2238G>A p.M746I | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NKX3-2 | c.385G>T p.V129F | Missense Mutation (SNP) | VAF 590/792 reads (74%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NLRC5 | c.377G>C p.S126T | Missense Mutation (SNP) | VAF 379/489 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NLRC5 | c.1858G>T p.D620Y | Missense Mutation (SNP) | VAF 431/572 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NLRP14 | c.379A>T p.R127* | Nonsense Mutation (SNP) | VAF 156/156 reads (100%) | called by muse, mutect2, varscan2
- NLRP3 | c.1937A>T p.D646V | Missense Mutation (SNP) | VAF 99/518 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLRP8 | c.1142G>A p.S381N | Missense Mutation (SNP) | VAF 150/329 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NOD1 | c.2426A>G p.K809R | Missense Mutation (SNP) | VAF 87/267 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NOL4L | c.467C>G p.T156S | Missense Mutation (SNP) | VAF 139/375 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NOP14 | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 153/702 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOP53 | c.506A>T p.Q169L | Missense Mutation (SNP) | VAF 133/698 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NOTCH4 | c.2684T>G p.I895R | Missense Mutation (SNP) | VAF 247/473 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NPAS1 | c.547T>A p.F183I | Missense Mutation (SNP) | VAF 136/657 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPC1 | c.120C>A p.Y40* | Nonsense Mutation (SNP) | VAF 80/397 reads (20%) | called by muse, mutect2, varscan2
- NR0B1 | c.1388T>C p.L463P | Missense Mutation (SNP) | VAF 158/158 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NSMAF | c.1312G>T p.G438C | Missense Mutation (SNP) | VAF 95/414 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NTNG2 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 265/266 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUTM1 | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 254/376 reads (68%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- NYAP1 | c.1555_1556delinsT p.G519Sfs*24 | Frame Shift Del (DEL) | VAF 116/858 reads (14%) | called by pindel, varscan2*
- OASL | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 180/403 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPN1LW | c.37C>A p.R13S | Missense Mutation (SNP) | VAF 118/161 reads (73%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- OPN1MW | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 249/273 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10A3 | c.783A>T p.Q261H | Missense Mutation (SNP) | VAF 120/379 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR11H2 | c.5A>T p.N2I (on ENST00000556246; = p.N13I on NM_001197287.1) | Missense Mutation (SNP) | VAF 88/201 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- OR12D3 | c.92T>C p.I31T | Missense Mutation (SNP) | VAF 271/526 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR13G1 | c.706T>A p.S236T | Missense Mutation (SNP) | VAF 94/481 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR14A2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 101/269 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- OR14C36 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 94/172 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR1A2 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 168/268 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- OR2B6 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 158/376 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR2J2 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 181/395 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- OR2J3 | c.405C>G p.Y135* | Nonsense Mutation (SNP) | VAF 306/732 reads (42%) | called by muse, mutect2
- OR2L5 | c.197C>A p.S66Y | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR51E1 | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 392/394 reads (99%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- OR5AS1 | c.291dup p.A98Cfs*12 | Frame Shift Ins (INS) | VAF 257/329 reads (78%) | called by mutect2, pindel, varscan2
- OR5K4 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 139/373 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OR5M1 | c.704A>T p.H235L | Missense Mutation (SNP) | VAF 223/249 reads (90%) | SIFT tolerated (0.2); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR6B2 | c.109T>A p.F37I | Missense Mutation (SNP) | VAF 108/396 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by mutect2, varscan2
- OR6V1 | c.754A>C p.S252R | Missense Mutation (SNP) | VAF 129/651 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- OR8S1 | c.333A>T p.E111D | Missense Mutation (SNP) | VAF 135/559 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSBPL1A | c.277C>G p.R93G | Missense Mutation (SNP) | VAF 104/392 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OSBPL5 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 450/450 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- OTOGL | c.5395C>A p.P1799T (on ENST00000547103; = p.P1790T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 233/320 reads (73%) | SIFT tolerated (0.23); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PARVB | c.367A>G p.K123E | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- PBRM1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 307/307 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PCDH1 | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 161/599 reads (27%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- PCDH11X | c.3104_3105delinsG p.P1035Rfs*86 | Frame Shift Del (DEL) | VAF 164/331 reads (50%) | called by pindel, varscan2*
- PCDHA12 | c.2325C>A p.S775R | Missense Mutation (SNP) | VAF 87/444 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PCDHA2 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 118/492 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); called by muse, mutect2
- PCDHA8 | c.1385T>C p.V462A | Missense Mutation (SNP) | VAF 193/771 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PCDHB14 | c.2128G>T p.A710S | Missense Mutation (SNP) | VAF 176/844 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PCDHB16 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 128/450 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- PCDHB7 | c.23C>A p.A8D | Missense Mutation (SNP) | VAF 73/318 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGA8 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 91/350 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCNX1 | c.5683G>T p.G1895W | Missense Mutation (SNP) | VAF 107/286 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNX1 | c.6900G>A p.W2300* | Nonsense Mutation (SNP) | VAF 85/273 reads (31%) | called by muse, mutect2, varscan2
- PCOLCE2 | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 82/625 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PDE6B | c.587T>A p.L196H | Missense Mutation (SNP) | VAF 439/554 reads (79%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- PDLIM7 | c.390G>T p.Q130H | Missense Mutation (SNP) | VAF 120/535 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEG3 | c.1309C>A p.P437T | Missense Mutation (SNP) | VAF 268/351 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PHKA2 | c.173del p.G58Afs*25 | Frame Shift Del (DEL) | VAF 341/475 reads (72%) | called by mutect2, pindel, varscan2
- PHLPP1 | c.460G>C p.A154P | Missense Mutation (SNP) | VAF 424/1316 reads (32%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- PIK3C2G | c.971A>G p.N324S | Missense Mutation (SNP) | VAF 328/415 reads (79%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PKDREJ | c.736C>A p.Q246K | Missense Mutation (SNP) | VAF 159/567 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKHD1L1 | c.7966T>A p.C2656S | Missense Mutation (SNP) | VAF 275/600 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PKHD1L1 | c.8828G>T p.R2943M | Missense Mutation (SNP) | VAF 207/456 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- PLAGL2 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 64/659 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLB1 | c.346T>A p.Y116N | Missense Mutation (SNP) | VAF 129/600 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLXNA3 | c.5145G>T p.W1715C | Missense Mutation (SNP) | VAF 267/267 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA4 | c.2341T>A p.L781M | Missense Mutation (SNP) | VAF 115/525 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PLXNB2 | c.3532G>T p.G1178C | Missense Mutation (SNP) | VAF 297/454 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNB3 | c.3551A>T p.E1184V | Missense Mutation (SNP) | VAF 367/368 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- PM20D1 | c.1238G>T p.R413L | Missense Mutation (SNP) | VAF 415/685 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- PNISR | c.961A>C p.S321R | Missense Mutation (SNP) | VAF 105/396 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNMA3 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 421/422 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- POLR2B | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 183/295 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- POU2F1 | c.333G>A p.G111= (on ENST00000541643 / NM_001365848.1; = p.G134= on NM_002697.4) | Splice Region (SNP) | VAF 259/341 reads (76%) | called by muse, mutect2, varscan2
- POU3F3 | c.1480G>T p.G494W | Missense Mutation (SNP) | VAF 96/310 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- PPM1N | c.448C>A p.R150S | Missense Mutation (SNP) | VAF 243/1007 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PPP1R16A | c.1030A>G p.S344G | Missense Mutation (SNP) | VAF 159/927 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- PPP2R3A | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 268/660 reads (41%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- PREPL | c.1426G>T p.V476L | Missense Mutation (SNP) | VAF 102/513 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PROB1 | c.1582G>T p.G528C | Missense Mutation (SNP) | VAF 499/685 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PRR16 | c.468T>A p.N156K (on ENST00000407149 / NM_001300783.2; = p.N133K on NM_016644.2) | Missense Mutation (SNP) | VAF 84/339 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- PSMB9 | c.584dup p.V196Gfs*17 | Frame Shift Ins (INS) | VAF 237/609 reads (39%) | called by mutect2, pindel, varscan2
- PTPRH | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 599/748 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- PTPRQ | c.191C>A p.S64Y (on ENST00000616559; = p.S22Y on NM_001145026.2) | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- PTPRR | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 264/378 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PXDN | c.4206+1G>A p.X1402_splice | Splice Site (SNP) | VAF 52/211 reads (25%) | called by muse, mutect2, varscan2
- PXDN | c.3695T>A p.L1232Q | Missense Mutation (SNP) | VAF 75/377 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PXDN | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 74/359 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- PXDNL | c.4304C>A p.P1435H | Missense Mutation (SNP) | VAF 74/284 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.722); called by muse, mutect2
- PXDNL | c.461A>T p.H154L | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- R3HDML | c.674G>T p.C225F | Missense Mutation (SNP) | VAF 196/485 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- RAB3C | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 101/393 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RAB4B | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 280/395 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RALGAPA2 | c.3886G>T p.D1296Y | Missense Mutation (SNP) | VAF 149/311 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- RAPH1 | c.1781G>C p.R594T | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RBBP6 | c.2912C>G p.T971R | Missense Mutation (SNP) | VAF 145/321 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RBM46 | c.26C>A p.T9K | Missense Mutation (SNP) | VAF 150/150 reads (100%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- RERE | c.1433dup p.S479Vfs*3 | Frame Shift Ins (INS) | VAF 280/382 reads (73%) | called by mutect2, pindel, varscan2
- RIMS2 | c.4385G>T p.G1462V (on ENST00000666250 / NM_001348490.2; = p.G1033V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 230/523 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF169 | c.577-18_598del p.X193_splice | Splice Site (DEL) | VAF 119/306 reads (39%) | called by mutect2, pindel, varscan2
- RRP9 | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 482/484 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTL6 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 368/547 reads (67%) | SIFT tolerated (0.34); PolyPhen benign (0); called by mutect2, varscan2
- RTN4RL1 | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 465/465 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- RYR1 | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 437/588 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.7211C>T p.P2404L | Missense Mutation (SNP) | VAF 79/418 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- S1PR4 | c.232C>G p.R78G | Missense Mutation (SNP) | VAF 232/666 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SATL1 | c.439C>G p.Q147E (on ENST00000395409; = p.Q334E on NM_001012980.2) | Missense Mutation (SNP) | VAF 332/333 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SEC23B | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 135/314 reads (43%) | called by muse, mutect2, varscan2
- SEC24D | c.973A>G p.M325V | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- SEMA5A | c.2129G>T p.W710L | Missense Mutation (SNP) | VAF 101/367 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SEMA6A | c.2887C>A p.P963T | Missense Mutation (SNP) | VAF 137/582 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERINC3 | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 211/341 reads (62%) | SIFT tolerated (0.63); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SERPINE2 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 129/405 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SEZ6L | c.2819C>A p.A940D | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.404); called by mutect2, varscan2
- SH3D21 | c.2149_2151dup p.D717dup (on ENST00000453908 / NM_001162530.2; = p.D606dup on NM_024676.5) | In Frame Ins (INS) | VAF 146/469 reads (31%) | called by mutect2, pindel, varscan2
- SIGLEC10 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 70/363 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- SIGLEC6 | c.915G>T p.E305D | Missense Mutation (SNP) | VAF 429/559 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SIRPG | c.932C>A p.T311K | Missense Mutation (SNP) | VAF 99/389 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC17A9 | c.212G>T p.W71L | Missense Mutation (SNP) | VAF 311/540 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLC1A7 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 491/493 reads (100%) | SIFT tolerated (0.93); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SLC27A6 | c.971G>T p.R324I | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- SLC37A3 | c.877A>T p.I293L | Missense Mutation (SNP) | VAF 239/348 reads (69%) | SIFT tolerated (0.54); PolyPhen benign (0.014); called by muse, mutect2
- SLC43A1 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 152/570 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SLC45A2 | c.572G>C p.G191A | Missense Mutation (SNP) | VAF 144/307 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC6A2 | c.1199G>C p.G400A | Missense Mutation (SNP) | VAF 101/492 reads (21%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- SLITRK4 | c.931_932insG p.K311Rfs*61 | Frame Shift Ins (INS) | VAF 282/392 reads (72%) | called by mutect2, pindel, varscan2
- SMARCC2 | c.2785G>C p.A929P | Missense Mutation (SNP) | VAF 288/432 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- SMARCD1 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 67/334 reads (20%) | called by mutect2, varscan2
- SMG8 | c.514G>T p.G172W | Missense Mutation (SNP) | VAF 387/388 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); called by mutect2, varscan2
- SMIM1 | c.230G>A p.C77Y | Missense Mutation (SNP) | VAF 310/310 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SNAP91 | c.1436C>A p.P479H | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SORD | c.634A>T p.K212* | Nonsense Mutation (SNP) | VAF 30/334 reads (9%) | called by muse, mutect2
- SOX6 | c.1956C>A p.S652R (on ENST00000528429 / NM_001145819.2; = p.S625R on NM_017508.3) | Missense Mutation (SNP) | VAF 199/199 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPATA19 | c.484C>G p.P162A | Missense Mutation (SNP) | VAF 372/474 reads (78%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPDL1 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 183/245 reads (75%) | called by muse, mutect2, varscan2
- SREBF2 | c.1694G>T p.R565L | Missense Mutation (SNP) | VAF 148/475 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SRRM2 | c.5536C>A p.P1846T | Missense Mutation (SNP) | VAF 195/811 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- SSTR5 | c.366C>A p.N122K | Missense Mutation (SNP) | VAF 217/1038 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- STAT5B | c.1075A>G p.K359E | Missense Mutation (SNP) | VAF 166/542 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- STOX1 | c.1894G>A p.G632R | Missense Mutation (SNP) | VAF 133/401 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- STRN | c.1492G>T p.A498S | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SULT4A1 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 143/395 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SYT16 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 101/304 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SYTL2 | c.2000+1G>T p.X667_splice (on ENST00000528231 / NM_001162951.2; = p.X643_splice on NM_032943.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 306/307 reads (100%) | called by muse, mutect2, varscan2
- TAF11L14 | c.412A>C p.M138L | Missense Mutation (SNP) | VAF 100/390 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAF1L | c.4736A>T p.H1579L | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- TAF1L | c.1171_1172del p.Q391Tfs*2 | Frame Shift Del (DEL) | VAF 52/338 reads (15%) | called by pindel, varscan2
- TAF4B | c.489G>T p.P163= | Splice Region (SNP) | VAF 147/278 reads (53%) | called by muse, mutect2, varscan2
- TARM1 | c.386G>C p.G129A (on ENST00000616041 / NM_001330650.1; = p.G121A on NM_001135686.3) | Missense Mutation (SNP) | VAF 80/394 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAS2R41 | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 77/319 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D3B | c.422A>T p.H141L | Missense Mutation (SNP) | VAF 298/693 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- TBC1D9 | c.2930G>T p.G977V | Missense Mutation (SNP) | VAF 87/322 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBX5 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 120/496 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TDRKH | c.423G>T p.G141= | Splice Region (SNP) | VAF 300/392 reads (77%) | called by muse, mutect2, varscan2
- TEKT5 | c.980_987del p.L327Sfs*19 | Frame Shift Del (DEL) | VAF 95/439 reads (22%) | called by mutect2, pindel, varscan2
- TENM2 | c.6709C>A p.P2237T (on ENST00000518659 / NM_001122679.2; = p.P1998T on NM_001080428.3) | Missense Mutation (SNP) | VAF 409/571 reads (72%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TENM3 | c.6868G>C p.D2290H | Missense Mutation (SNP) | VAF 265/265 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- TEPP | c.195G>A p.W65* | Nonsense Mutation (SNP) | VAF 96/419 reads (23%) | called by muse, mutect2, varscan2
- TEX51 | c.197T>A p.L66H | Missense Mutation (SNP) | VAF 134/267 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFF2 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 250/250 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TG | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 222/695 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TGIF2LX | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 278/279 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TGM7 | c.1424C>A p.P475H | Missense Mutation (SNP) | VAF 323/477 reads (68%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- THG1L | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 76/405 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TIMD4 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- TMEM161B | c.1456G>T p.V486L | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- TMEM179 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 303/471 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- TMEM229A | c.460_471del p.P154_L157del | In Frame Del (DEL) | VAF 102/513 reads (20%) | called by pindel, varscan2
- TMTC2 | c.2503A>G p.K835E | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNNI3K | c.1668-1G>C p.X556_splice | Splice Site (SNP) | VAF 59/206 reads (29%) | called by muse, mutect2, varscan2
- TNR | c.1553C>A p.T518N | Missense Mutation (SNP) | VAF 292/386 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TOP2B | c.456G>C p.K152N (on ENST00000264331 / NM_001330700.2; = p.K147N on NM_001068.3) | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TOPAZ1 | c.73C>G p.R25G | Missense Mutation (SNP) | VAF 300/300 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- TPR | c.6623G>T p.G2208V | Missense Mutation (SNP) | VAF 210/298 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRAJ46 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 131/427 reads (31%) | PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TRAP1 | c.1951A>T p.I651F | Missense Mutation (SNP) | VAF 374/496 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRAPPC8 | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); called by muse, varscan2
- TRAV40 | c.194A>T p.Q65L | Missense Mutation (SNP) | VAF 113/357 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRBV23-1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 262/359 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- TRBV27 | c.31del p.L11Ffs*4 | Frame Shift Del (DEL) | VAF 289/526 reads (55%) | called by mutect2, pindel, varscan2
- TRDD3 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 92/330 reads (28%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRHDE | c.1414del p.V472Lfs*18 | Frame Shift Del (DEL) | VAF 200/375 reads (53%) | called by mutect2, pindel, varscan2
- TRIM64B | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 212/422 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM66 | c.2785G>A p.V929I | Missense Mutation (SNP) | VAF 95/323 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TRIM9 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 174/578 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TRIP10 | c.1317C>A p.D439E (on ENST00000313244 / NM_001288962.2; = p.D383E on NM_004240.4) | Missense Mutation (SNP) | VAF 256/414 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TTC28 | c.2716G>C p.V906L | Missense Mutation (SNP) | VAF 209/319 reads (66%) | SIFT tolerated (0.57); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TTLL4 | c.1237G>T p.V413F | Missense Mutation (SNP) | VAF 134/411 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- TTN | c.98916T>A p.D32972E (on ENST00000591111; = p.D25548E on NM_003319.4) | Missense Mutation (SNP) | VAF 94/264 reads (36%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.89741G>C p.R29914P (on ENST00000591111; = p.R22490P on NM_003319.4) | Missense Mutation (SNP) | VAF 128/418 reads (31%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.77872G>T p.G25958C (on ENST00000591111; = p.G18534C on NM_003319.4) | Missense Mutation (SNP) | VAF 75/286 reads (26%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.75548C>A p.T25183N (on ENST00000591111; = p.T17759N on NM_003319.4) | Missense Mutation (SNP) | VAF 104/343 reads (30%) | PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TTN | c.71793C>A p.N23931K (on ENST00000591111; = p.N16507K on NM_003319.4) | Missense Mutation (SNP) | VAF 126/432 reads (29%) | PolyPhen benign (0.372); called by muse, mutect2, varscan2
- TTN | c.64003C>T p.L21335F (on ENST00000591111; = p.L13911F on NM_003319.4) | Missense Mutation (SNP) | VAF 157/427 reads (37%) | PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- TTN | c.58436A>G p.N19479S (on ENST00000591111; = p.N12055S on NM_003319.4) | Missense Mutation (SNP) | VAF 123/376 reads (33%) | PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTN | c.20352G>C p.L6784F (on ENST00000591111; = p.L5857F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/388 reads (31%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUBGCP6 | c.5032A>G p.K1678E | Missense Mutation (SNP) | VAF 309/485 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- TXNDC5 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 192/410 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- U2SURP | c.2670G>T p.E890D | Missense Mutation (SNP) | VAF 132/275 reads (48%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- UBE3A | c.2134G>C p.E712Q | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- UBR5 | c.6177A>G p.P2059= | Splice Region (SNP) | VAF 264/485 reads (54%) | called by muse, mutect2, varscan2
- UNC13A | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 167/542 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- UNC79 | c.7091G>T p.G2364V (on ENST00000393151 / NM_001346218.2; = p.G2187V on NM_020818.5) | Missense Mutation (SNP) | VAF 224/727 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- UNC80 | c.2402del p.G801Dfs*18 | Frame Shift Del (DEL) | VAF 131/395 reads (33%) | called by mutect2, pindel, varscan2
- UNC80 | c.5014-1G>T p.X1672_splice | Splice Site (SNP) | VAF 95/247 reads (38%) | called by muse, mutect2, varscan2
- USH2A | c.11425G>T p.V3809F | Missense Mutation (SNP) | VAF 59/308 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- USP2 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 668/669 reads (100%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- UXS1 | c.1121G>T p.W374L | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VAV3 | c.717+1G>C p.X239_splice | Splice Site (SNP) | VAF 187/187 reads (100%) | called by muse, mutect2, varscan2
- VLDLR | c.1187-1G>C p.X396_splice | Splice Site (SNP) | VAF 82/139 reads (59%) | called by muse, mutect2, varscan2
- WAC | c.843T>A p.D281E | Missense Mutation (SNP) | VAF 116/369 reads (31%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- WIPF3 | c.307G>C p.A103P | Missense Mutation (SNP) | VAF 208/338 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XIRP2 | c.380A>T p.E127V (on ENST00000628543; = p.E302V on NM_152381.6) | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- XYLT1 | c.1454A>G p.E485G | Missense Mutation (SNP) | VAF 133/599 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB46 | c.799A>G p.T267A | Missense Mutation (SNP) | VAF 207/513 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZFHX3 | c.6501C>A p.N2167K | Missense Mutation (SNP) | VAF 90/407 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZIM2 | c.1468C>G p.Q490E | Missense Mutation (SNP) | VAF 276/362 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ZNF180 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 128/582 reads (22%) | called by muse, mutect2, varscan2
- ZNF28 | c.1621C>T p.H541Y | Missense Mutation (SNP) | VAF 68/321 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF300 | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 102/394 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF382 | c.1159A>T p.S387C | Missense Mutation (SNP) | VAF 66/283 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ZNF407 | c.3187A>G p.R1063G | Missense Mutation (SNP) | VAF 159/334 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
278 further variants in this file (14 protein-altering or splice-affecting, 224 silent, 40 other) are not listed here.
